Somatic mutation profile of tumor specimen ALCH-B1XZ-TTP1-A (aliquot ALCH-B1XZ-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1XZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,310 days).
Specimen ALCH-B1XZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 101251a1-9bc2-4a99-8efc-440518ae9caf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1XZ-NB1-A (Blood Derived Normal), aliquot ALCH-B1XZ-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47f545a5-6810-43af-a3eb-dc6094e488d0

The open-access MAF lists 1,132 somatic variants for this specimen: 798 protein-altering or splice-affecting, 214 silent, 120 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 661, Silent 214, Nonsense Mutation 59, Intron 46, Frame Shift Del 29, Splice Site 25, RNA 24, 5'UTR 19, 3'UTR 18, Splice Region 14, 5'Flank 11, Frame Shift Ins 6.

Variants (750 of 1,132; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/540 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 98/274 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1724C>A p.S575* | Nonsense Mutation (SNP) | VAF 94/217 reads (43%) | catalogued as COSV100588912; called by muse, mutect2, varscan2
- AAMP | c.845G>T p.C282F | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.506); catalogued as COSV50306793; called by muse, mutect2, varscan2
- ABL1 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104403965; called by muse, mutect2, varscan2
- ACTL9 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100185290, COSV61007537; called by muse, mutect2
- ADAR | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs762488180; called by muse, mutect2, varscan2
- ADARB1 | c.1988G>A p.R663H (on ENST00000360697 / NM_001346687.2; = p.R623H on NM_001112.4) | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as rs775065806, COSV100654187; called by muse, mutect2, varscan2
- ADCY1 | c.3216del p.M1074Cfs*65 | Frame Shift Del (DEL) | VAF 105/462 reads (23%) | catalogued as COSV52035143; called by mutect2, pindel, varscan2
- ADGB | c.3851G>T p.S1284I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58849420; called by muse, mutect2, varscan2
- ADGRL4 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs191635062; called by muse, varscan2
- ALOX5 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 30/608 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746046438, COSV65551675; called by muse, mutect2
- AMER3 | c.95A>T p.E32V | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58465178; called by muse, mutect2, varscan2
- AMOTL1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 42/513 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54418892; called by muse, mutect2
- ANO3 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1195721937; called by muse, mutect2, varscan2
- APOB | c.12495G>T p.Q4165H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV51945549; called by muse, mutect2, varscan2
- AR | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1419690127, COSV65955958, COSV65965297; called by muse, mutect2, varscan2
- AR | c.2702C>A p.S901Y | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101017255; called by muse, mutect2, varscan2
- ARHGEF3 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs768081587; called by muse, mutect2, varscan2
- ARID3B | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV60556387, COSV60558258; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1136del p.P379Lfs*3 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as COSV63437311; called by mutect2, pindel, varscan2
- ASB17 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs950670142; called by muse, mutect2
- ASTN1 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs751815220, COSV56064909; called by muse, mutect2, varscan2
- ASXL2 | c.195A>T p.R65S | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1271947311; called by muse, mutect2, varscan2
- BPIFB3 | c.1250A>G p.H417R | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1364919305; called by muse, mutect2, varscan2
- BRINP2 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs751983601, COSV64176567; called by muse, mutect2, varscan2
- C20orf96 | c.20+2T>A p.X7_splice (on ENST00000360321 / NM_153269.3; = p.S5R on NM_080571.1) | Splice Site (SNP) | VAF 54/208 reads (26%) | catalogued as rs767300766; called by mutect2, varscan2
- CADM1 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 140/502 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.264); catalogued as COSV59018813, COSV59020355; called by muse, mutect2, varscan2
- CC2D2A | c.1286C>A p.A429D | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1473245949; called by muse, mutect2, varscan2
- CD34 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.19); catalogued as COSV60413118, COSV60415617; called by muse, mutect2
- CDC42BPA | c.2995G>T p.G999* (on ENST00000334218 / NM_001366019.2; = p.G986* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/290 reads (17%) | catalogued as COSV100503346; called by muse, mutect2, varscan2
- CDH5 | c.2262C>A p.D754E | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs1281222213; called by muse, mutect2, varscan2
- CDH9 | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV99161395; called by muse, mutect2, varscan2
- CEACAM20 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 48/225 reads (21%) | catalogued as COSV57603063; called by muse, mutect2, varscan2
- CEACAM6 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 55/509 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV99555785; called by muse, mutect2, varscan2
- CELSR3 | c.6369G>T p.R2123= | Splice Region (SNP) | VAF 44/150 reads (29%) | catalogued as COSV51166390; called by muse, mutect2, varscan2
- CFAP73 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1365267163; called by muse, mutect2, varscan2
- CFH | c.2563G>C p.D855H | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV66410391; called by muse, mutect2, varscan2
- CHDH | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV99858537; called by muse, mutect2, varscan2
- CHST8 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV52858558; called by muse, mutect2, varscan2
- CIZ1 | c.1637del p.G546Afs*3 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | catalogued as rs1204309309; called by mutect2, pindel
- CNNM1 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1050256791, COSV100763895; called by muse, mutect2, varscan2
- CNTNAP2 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV62228409; called by muse, mutect2
- COL5A2 | c.3014G>T p.G1005V | Missense Mutation (SNP) | VAF 112/529 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66408186; called by muse, mutect2, varscan2
- CPEB3 | c.803C>G p.P268R | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.994); catalogued as rs1181514512; called by muse, mutect2
- CPXM1 | c.731C>A p.P244Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV66046251; called by muse, mutect2, varscan2
- CSMD3 | c.4835G>T p.R1612I (on ENST00000297405 / NM_001363185.1; = p.R1508I on NM_052900.3) | Missense Mutation (SNP) | VAF 116/581 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV52129646; called by muse, mutect2, varscan2
- CSN2 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61991811, COSV61992523; called by muse, mutect2, varscan2
- CTDSPL | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.019); catalogued as rs998550228; called by muse, varscan2
- CTRB2 | c.52+8C>A | Splice Region (SNP) | VAF 101/251 reads (40%) | catalogued as rs1275621348; called by muse, mutect2, varscan2
- CYB5R4 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV63751125; called by muse, mutect2, varscan2
- DCHS1 | c.1265A>T p.Y422F | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs200893325, COSV55034272; called by muse, mutect2, varscan2
- DEFA4 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as rs754417143; called by muse, mutect2, varscan2
- DENND2C | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 12/189 reads (6%) | catalogued as rs1249021503; called by muse, mutect2
- DENR | c.47A>G p.D16G | Missense Mutation (SNP) | VAF 105/439 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs376973866; called by muse, mutect2, varscan2
- DGKQ | c.1955G>A p.W652* | Nonsense Mutation (SNP) | VAF 20/126 reads (16%) | catalogued as rs1276394840; called by muse, mutect2, varscan2
- DIS3L | c.1178T>C p.V393A (on ENST00000319212 / NM_001143688.3; = p.V310A on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs761463282, COSV59912166; called by muse, mutect2
- DMD | c.1704+1G>T p.X568_splice | Splice Site (SNP) | VAF 107/236 reads (45%) | catalogued as CS140197, CS150624; called by muse, mutect2, varscan2
- DNAH14 | c.8974G>A p.A2992T | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated, low confidence (0.36); catalogued as rs1474019727; called by muse, mutect2
- DNAH7 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); catalogued as rs1254889850; called by muse, mutect2, varscan2
- EGR4 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1026012095; called by muse, mutect2, varscan2
- ELAVL4 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.12); catalogued as COSV63914781, COSV63917963; called by muse, mutect2, varscan2
- EPRS1 | c.2981G>A p.G994E | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1301504225; called by muse, mutect2, varscan2
- EPX | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 36/467 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs776191129, COSV99836714; called by muse, mutect2
- EXO1 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62216220, COSV62216256; called by muse, mutect2, varscan2
- EXO1 | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | catalogued as COSV62219089; called by muse, mutect2, varscan2
- FAM47A | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 115/200 reads (58%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as COSV60496260; called by muse, mutect2, varscan2
- FCGR3A | c.195C>A p.S65R | Missense Mutation (SNP) | VAF 246/1917 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs747670473, COSV63460086; called by muse, varscan2
- FCHO2 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99821527, COSV99821840; called by muse, mutect2, varscan2
- FLG | c.8840C>A p.S2947Y | Missense Mutation (SNP) | VAF 60/576 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV100911258; called by muse, mutect2, varscan2
- FLOT2 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.501); catalogued as COSV99076777; called by muse, mutect2
- FMN2 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as rs200364388; called by muse, mutect2, varscan2
- FREM3 | c.3701C>A p.A1234D | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.094); catalogued as rs765343323; called by muse, mutect2, varscan2
- GALNT9 | c.1183C>T p.R395C (on ENST00000328957 / NM_001122636.2; = p.R29C on NM_021808.3) | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs781207265; called by muse, mutect2, varscan2
- GALNTL6 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV101487672; called by muse, mutect2, varscan2
- GJC2 | c.679T>A p.F227I | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553262546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GK3P | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV56979567; called by muse, mutect2, varscan2
- GLT1D1 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1276196383, COSV55880167; called by muse, mutect2, varscan2
- GMDS | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV66428662; called by muse, mutect2, varscan2
- GOLGA3 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.04); catalogued as COSV52641170; called by muse, mutect2, varscan2
- GRIN2D | c.1057C>A p.R353S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.346); catalogued as rs377464612; called by muse, mutect2, varscan2
- GRIN3A | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 163/694 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100701932; called by muse, mutect2, varscan2
- GRIN3A | c.456G>C p.M152I | Missense Mutation (SNP) | VAF 161/689 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV62451833; called by muse, mutect2, varscan2
- GRM6 | c.1633G>T p.G545W | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51437117; called by muse, mutect2, varscan2
- GUSBP10 | n.182G>A | Splice Region (SNP) | VAF 32/98 reads (33%) | catalogued as rs1214343507; called by muse, mutect2, varscan2
- HDAC9 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV67778170; called by muse, mutect2, varscan2
- HDAC9 | c.2673C>A p.F891L | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV67788082; called by muse, varscan2
- HEPH | c.3419G>A p.R1140Q (on ENST00000343002; = p.R873Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/193 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs757725630, COSV57972226; called by muse, mutect2, varscan2
- HMCN1 | c.1250G>C p.R417T | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99625904; called by muse, mutect2
- HMGCS2 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 58/652 reads (9%) | catalogued as rs1380312324, COSV65567900; called by muse, mutect2
- HOXA7 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 40/358 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1449685607, COSV54217425; called by muse, mutect2, varscan2
- HRG | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs141595547; called by muse, mutect2, varscan2
- HSF4 | c.307C>G p.H103D | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV50458144; called by muse, mutect2, varscan2
- HTR1A | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 196/515 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100109033; called by muse, varscan2
- HYAL4 | c.645G>T p.W215C | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs532897017, COSV56138602; called by muse, mutect2
- ICE1 | c.1669G>T p.G557* | Nonsense Mutation (SNP) | VAF 57/338 reads (17%) | catalogued as COSV56828005; called by muse, mutect2, varscan2
- IGKV3D-11 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 93/388 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs761700531; called by muse, mutect2, varscan2
- INHBA | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54219588, COSV54225084; called by muse, mutect2, varscan2
- JPH2 | c.999C>A p.D333E | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.433); catalogued as COSV65904055; called by muse, mutect2, varscan2
- KCNA5 | c.1281G>T p.L427F | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs375737581; called by muse, mutect2, varscan2
- KCNC1 | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.83); catalogued as COSV99789299; called by muse, mutect2, varscan2
- KCNJ11 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.69); catalogued as CM040762; called by mutect2, varscan2
- KCNQ2 | c.2281G>T p.A761S (on ENST00000359125 / NM_172107.4; = p.A733S on NM_004518.6) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.19); catalogued as rs587780366, COSV60554335; called by muse, mutect2, varscan2
- KCNT1 | c.1266C>A p.D422E (on ENST00000488444; = p.D441E on NM_020822.3) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368477306; called by muse, mutect2, varscan2
- KCNU1 | c.1192del p.E398Rfs*3 | Frame Shift Del (DEL) | VAF 61/314 reads (19%) | catalogued as COSV101299346; called by mutect2, pindel, varscan2
- KIAA0232 | c.3034G>T p.G1012* | Nonsense Mutation (SNP) | VAF 42/129 reads (33%) | catalogued as COSV100300243; called by muse, mutect2, varscan2
- KIAA1210 | c.3104C>G p.S1035* | Nonsense Mutation (SNP) | VAF 20/130 reads (15%) | catalogued as COSV68175248; called by muse, mutect2, varscan2
- KITLG | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV57203908; called by muse, mutect2, varscan2
- KRCC1 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.603); catalogued as COSV61252242; called by muse, mutect2, varscan2
- KRT6C | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 88/861 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs535131158, COSV52880586; called by muse, mutect2, varscan2
- KRT82 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 101/381 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV57786350; called by muse, mutect2, varscan2
- LBHD1 | c.630A>T p.E210D (on ENST00000431002 / NM_001367940.1; = p.E184D on NM_024099.3) | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); catalogued as COSV63473391; called by muse, mutect2, varscan2
- LDLRAD3 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV59677745, COSV59689925; called by muse, mutect2, varscan2
- LETM2 | c.824G>A p.R275H (on ENST00000379957 / NM_001286819.2; = p.R180H on NM_144652.3) | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs769707508, COSV52687376, COSV52688087; called by muse, mutect2, varscan2
- LRP5 | c.3581G>T p.R1194L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV53716124; called by muse, mutect2, varscan2
- LRRC52 | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.011); catalogued as rs768095663; called by muse, mutect2, varscan2
- LRRC7 | c.508G>A p.D170N (on ENST00000651989 / NM_001370785.2; = p.D137N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99225841; called by muse, mutect2, varscan2
- LRRTM4 | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV69142997; called by muse, mutect2, varscan2
- LUM | c.260A>T p.E87V | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV57128284; called by muse, mutect2, varscan2
- MAD1L1 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs1282487375; called by muse, mutect2, varscan2
- MAP2K7 | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607630; called by muse, mutect2
- MARCHF11 | c.764T>A p.L255* | Nonsense Mutation (SNP) | VAF 148/491 reads (30%) | catalogued as COSV60128180; called by muse, mutect2, varscan2
- MCF2 | c.293T>C p.I98T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1188030223; called by muse, mutect2, varscan2
- MED1 | c.3874G>A p.G1292R | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs746401810; called by muse, mutect2, varscan2
- MEX3D | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs762451611; called by muse, mutect2, varscan2
- MMAB | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 124/509 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as CM153583, COSV57169638, COSV57170786; called by muse, mutect2, varscan2
- MTCL1 | c.3752G>A p.R1251H (on ENST00000306329 / NM_001378206.1; = p.R932H on NM_015210.4) | Missense Mutation (SNP) | VAF 112/466 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as rs765671835; called by muse, mutect2, varscan2
- MUC16 | c.41336C>G p.S13779W | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV66691275, COSV66692705; called by muse, mutect2, varscan2
- MUC16 | c.39352C>A p.L13118M | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66689863; called by muse, mutect2, varscan2
- MUC5AC | c.13661C>A p.T4554N | Missense Mutation (SNP) | VAF 99/432 reads (23%) | SIFT tolerated (0.09); catalogued as COSV64369606; called by muse, varscan2
- MVP | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 85/372 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs200776716; called by muse, mutect2, varscan2
- MYBPC3 | c.1445C>A p.A482E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57030287; called by muse, mutect2
- MYMK | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs1359160713; called by muse, mutect2, varscan2
- MYO16 | c.2936C>A p.A979D | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs757480622; called by muse, varscan2
- MYOC | c.1052C>A p.T351N | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as rs760271913; called by muse, mutect2, varscan2
- NBEAL1 | c.4339A>G p.I1447V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV71374096; called by muse, varscan2
- NCOR1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99252267; called by muse, mutect2, varscan2
- NDST4 | c.1339A>T p.S447C | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52111878; called by muse, mutect2, varscan2
- NEB | c.2521G>T p.D841Y | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377599060; called by muse, mutect2, varscan2
- NF1 | c.6006+1G>T p.X2002_splice (on ENST00000358273 / NM_001042492.3; = p.X1981_splice on NM_000267.3) | Splice Site (SNP) | VAF 33/154 reads (21%) | catalogued as CS000882, CS040855, COSV99049985; called by muse, mutect2, varscan2
- NKX6-2 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs767605991; called by mutect2, varscan2
- NLGN1 | c.2146C>G p.R716G | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV64328746; called by muse, mutect2, varscan2
- NLRC5 | c.3028G>C p.D1010H | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52648144; called by muse, mutect2, varscan2
- NLRC5 | c.4018G>C p.V1340L | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as rs199476003, COSV52660983; called by muse, mutect2, varscan2
- NLRP8 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs1175879328; called by muse, mutect2, varscan2
- NOTCH1 | c.5311G>C p.E1771Q | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV53047111; called by muse, mutect2
- NOTCH2 | c.7358G>A p.R2453Q | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.805); catalogued as rs145366664, COSV56683726; called by muse, mutect2, varscan2
- NPAP1 | c.3131G>T p.G1044V | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.781); catalogued as COSV100276228; called by muse, mutect2, varscan2
- NR5A2 | c.404G>T p.R135I (on ENST00000367362 / NM_205860.3; = p.R89I on NM_003822.5) | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52646936, COSV99371661; called by muse, mutect2, varscan2
- OAS3 | c.3017G>A p.R1006H | Missense Mutation (SNP) | VAF 93/375 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); catalogued as rs372426187; called by muse, mutect2, varscan2
- OCSTAMP | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1392108606, COSV99645482; called by muse, mutect2, varscan2
- OPRPN | c.296T>G p.F99C | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV68192948; called by muse, mutect2, varscan2
- OR10K1 | c.911C>A p.T304K | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs541266030, COSV56873772; called by muse, mutect2
- OR14C36 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.107); catalogued as COSV58601737; called by muse, mutect2, varscan2
- OR1L4 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 96/532 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs753003615; called by muse, varscan2
- OR2AJ1 | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 122/564 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59089693; called by muse, mutect2, varscan2
- OR2F1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 97/373 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as rs868094811; called by muse, mutect2, varscan2
- OR2T2 | c.706C>G p.R236G | Missense Mutation (SNP) | VAF 155/1700 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV100737564; called by muse, mutect2
- OR2T3 | c.488T>G p.L163W | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1457024522; called by muse, mutect2, varscan2
- OR4N2 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1347165866; called by muse, mutect2
- OR4N2 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 70/495 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60055551; called by muse, mutect2, varscan2
- OR52N1 | c.402T>A p.Y134* | Nonsense Mutation (SNP) | VAF 116/398 reads (29%) | catalogued as COSV57693807; called by muse, mutect2, varscan2
- OR5M1 | c.405G>T p.R135S | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs772658917, COSV101591543, COSV73202111; called by muse, mutect2, varscan2
- OR6F1 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 107/439 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100129402, COSV57469581; called by muse, mutect2, varscan2
- OR6Y1 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 98/484 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56930111; called by muse, mutect2, varscan2
- OXCT2 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 41/210 reads (20%) | catalogued as rs752977074, COSV59593104; called by muse, mutect2, varscan2
- PCDH15 | c.5224C>T p.P1742S | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV57369631; called by muse, mutect2
- PCDH15 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 118/674 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100218232; called by muse, mutect2, varscan2
- PCDHA13 | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 122/358 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781987468; called by muse, mutect2, varscan2
- PCDHA6 | c.1649C>A p.T550K | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV65341800; called by muse, mutect2, varscan2
- PCDHGA2 | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.304); catalogued as COSV54007089; called by muse, mutect2, varscan2
- PDGFC | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV56844615; called by muse, mutect2, varscan2
- PDZRN3 | c.2839G>T p.A947S | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55195692; called by muse, mutect2, varscan2
- PDZRN3 | c.2577C>A p.Y859* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV55214657; called by muse, mutect2, varscan2
- PDZRN4 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 87/387 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as rs1313070170, COSV68412417; called by muse, mutect2, varscan2
- PHF8 | c.916C>T p.R306C (on ENST00000357988 / NM_001184896.1; = p.R270C on NM_015107.3) | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs782033442, COSV100153799, COSV100153804; called by muse, mutect2, varscan2
- PHRF1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs930157776; called by mutect2, varscan2
- PIKFYVE | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 126/482 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV100010811, COSV52238895; called by muse, mutect2, varscan2
- PLAA | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs776787686; called by muse, mutect2, varscan2
- PLCB1 | c.3294G>T p.M1098I | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62052526; called by muse, varscan2
- PLCL2 | c.2483G>T p.R828L (on ENST00000615277 / NM_001144382.2; = p.R702L on NM_015184.5) | Missense Mutation (SNP) | VAF 146/588 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67624282; called by muse, varscan2
- PLD5 | c.442G>C p.D148H (on ENST00000442594; = p.D86H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV59154342, COSV59168792; called by muse, varscan2
- PLEKHG3 | c.592G>T p.V198L (on ENST00000394691; = p.V254L on NM_001308147.2) | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs753254426, COSV55982739; called by muse, varscan2
- POLE3 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55913437; called by muse, mutect2, varscan2
- POM121L12 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs1454121607, COSV68693557; called by muse, mutect2, varscan2
- POP1 | c.1765G>C p.G589R | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV62891777; called by muse, mutect2, varscan2
- PPP2R2C | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as COSV100160705; called by muse, mutect2, varscan2
- PRAMEF4 | c.875G>T p.S292I | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs756831732; called by muse, mutect2, varscan2
- PRKAG1 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs199513404; called by muse, mutect2, varscan2
- PRKCG | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 168/594 reads (28%) | catalogued as COSV54723587; called by muse, mutect2, varscan2
- PRKCQ | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 116/277 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs753167345, COSV54109161; called by muse, mutect2, varscan2
- PRR23B | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61494238; called by muse, mutect2, varscan2
- PTPRD | c.2563G>T p.G855C | Missense Mutation (SNP) | VAF 56/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100644805; called by muse, varscan2
- PYHIN1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs1207242767, COSV63722813; called by muse, mutect2, varscan2
- RABGGTA | c.1030del p.D344Tfs*48 | Frame Shift Del (DEL) | VAF 56/294 reads (19%) | catalogued as COSV53769358; called by mutect2, pindel, varscan2
- RADIL | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs764336449, COSV68201628; called by muse, varscan2
- RAG2 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104398640; called by muse, mutect2, varscan2
- RANBP2 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51700365; called by muse, mutect2, varscan2
- RBMXL2 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV60979848; called by muse, mutect2, varscan2
- RBMXL3 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 16/26 reads (62%) | catalogued as rs1556557215; called by muse, mutect2
- RETSAT | c.1772A>C p.N591T | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV55524568; called by muse, mutect2, varscan2
- RFX6 | c.1133G>T p.R378I | Missense Mutation (SNP) | VAF 103/339 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV100263422; called by muse, mutect2, varscan2
- RGS18 | c.348G>T p.W116C | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66507160; called by muse, mutect2, varscan2
- RPA3 | c.323A>T p.D108V | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV56190212; called by muse, mutect2, varscan2
- RREB1 | c.2389G>T p.A797S | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV58565225; called by muse, mutect2, varscan2
- RTEL1 | c.2981T>C p.L994P | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1453207384, COSV58899864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAFB | c.2133del p.R712Gfs*60 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as COSV99412417; called by mutect2, pindel, varscan2
- SCP2 | c.512T>C p.M171T | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1278011245; called by muse, mutect2, varscan2
- SELP | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs552895990, COSV55248147; called by muse, mutect2
- SELP | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 91/413 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs906658177; called by muse, mutect2, varscan2
- SEMA3B | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs782631622; called by muse, mutect2, varscan2
- SFXN2 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs768428674, COSV64012019, COSV64013059; called by muse, mutect2, varscan2
- SIRPA | c.696C>A p.H232Q | Missense Mutation (SNP) | VAF 104/464 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61537567; called by muse, mutect2, varscan2
- SLC12A1 | c.2114C>A p.T705N | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV66799095; called by muse, mutect2, varscan2
- SLC12A9 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV51931830; called by muse, mutect2, varscan2
- SLC17A6 | c.323del p.G108Afs*19 | Frame Shift Del (DEL) | VAF 41/163 reads (25%) | catalogued as COSV54139110; called by mutect2, pindel
- SLC17A8 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 157/603 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV60122539; called by muse, mutect2, varscan2
- SLC1A6 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV55671011; called by muse, mutect2, varscan2
- SLC24A5 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479023500; called by muse, mutect2, varscan2
- SLC39A12 | c.1573G>T p.G525C (on ENST00000377369 / NM_001145195.2; = p.G488C on NM_152725.3) | Missense Mutation (SNP) | VAF 180/364 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV101070075; called by muse, varscan2
- SLC41A1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 136/542 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV65650279; called by muse, mutect2, varscan2
- SLC43A3 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs375121642; called by muse, mutect2, varscan2
- SLC45A2 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 188/485 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV99672701; called by muse, mutect2, varscan2
- SLC5A9 | c.1014C>G p.I338M | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV52582589; called by muse, mutect2, varscan2
- SLITRK1 | c.1371C>A p.N457K | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV65675285; called by muse, mutect2, varscan2
- SMAD3 | c.253C>G p.H85D | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100529009; called by muse, mutect2, varscan2
- SMARCD1 | c.1282A>G p.I428V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs762849068; called by mutect2, varscan2
- SMOC2 | c.781G>A p.V261I (on ENST00000356284 / NM_001166412.2; = p.V272I on NM_022138.3) | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs554225332, COSV100634634; called by muse, mutect2
- SNRNP200 | c.5022C>T p.H1674= | Splice Region (SNP) | VAF 46/424 reads (11%) | catalogued as rs139015042; ClinVar: likely benign; called by muse, mutect2
- SNRPB | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); catalogued as COSV60014946; called by muse, mutect2, varscan2
- SNX14 | c.1926G>T p.K642N (on ENST00000314673 / NM_001350535.1; = p.K589N on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59016749; called by muse, mutect2, varscan2
- SOS1 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV67674367; called by muse, mutect2
- SP140 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 42/189 reads (22%) | catalogued as COSV104415539, COSV59446882; called by muse, mutect2, varscan2
- SP9 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1489507680; called by muse, mutect2, varscan2
- SPAST | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs766958052, COSV100188553; called by muse, mutect2, varscan2
- SPATA13 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.828); catalogued as rs748908677; called by muse, mutect2, varscan2
- SPEG | c.7436del p.G2479Afs*140 | Frame Shift Del (DEL) | VAF 43/192 reads (22%) | catalogued as rs1559424095; called by mutect2, pindel, varscan2
- SPTA1 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 152/868 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV63748349; called by muse, mutect2, varscan2
- ST6GAL2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | PolyPhen benign (0.015); catalogued as COSV64530046, COSV64531712; called by muse, mutect2, varscan2
- ST8SIA3 | c.992G>C p.R331T | Missense Mutation (SNP) | VAF 101/283 reads (36%) | PolyPhen benign (0.113); catalogued as COSV60653476; called by muse, mutect2, varscan2
- STOX1 | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1408814346; called by muse, mutect2, varscan2
- SUPV3L1 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV62845835; called by muse, mutect2, varscan2
- SYT3 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58898156; called by muse, mutect2, varscan2
- SYT5 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs775205527; called by muse, mutect2, varscan2
- TBC1D4 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV66492466; called by muse, mutect2, varscan2
- TBX18 | c.1383C>A p.S461R | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.07); catalogued as rs779618643; called by muse, mutect2, varscan2
- TBX19 | c.730G>T p.G244* | Nonsense Mutation (SNP) | VAF 155/815 reads (19%) | catalogued as COSV63196573; called by muse, mutect2, varscan2
- TBX5 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM083178, COSV59860710; called by muse, mutect2, varscan2
- TCHH | c.5184G>T p.E1728D | Missense Mutation (SNP) | VAF 160/429 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV64274169; called by muse, mutect2, varscan2
- TCHH | c.4055C>A p.P1352Q | Missense Mutation (SNP) | VAF 77/418 reads (18%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs1437786153; called by muse, mutect2, varscan2
- TCHHL1 | c.1947del p.N650Mfs*21 | Frame Shift Del (DEL) | VAF 94/506 reads (19%) | catalogued as COSV64287379; called by mutect2, pindel, varscan2
- TLR4 | c.503C>A p.P168H (on ENST00000355622 / NM_138554.5; = p.P128H on NM_003266.4) | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281579352; called by muse, mutect2, varscan2
- TRAV36DV7 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.281); catalogued as rs1481288838; called by muse, mutect2
- UGT1A1 | c.115C>A p.H39N | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM002646; called by muse, mutect2, varscan2
- USP28 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 96/459 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1311028466, COSV50165788; called by muse, mutect2, varscan2
- VAPB | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1362788253, COSV55668013; called by muse, mutect2, varscan2
- VAV3 | c.1514G>T p.R505I | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.194); catalogued as COSV100579330; called by muse, mutect2, varscan2
- WNT4 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51602926; called by muse, mutect2, varscan2
- XKR4 | c.1451C>A p.A484E | Missense Mutation (SNP) | VAF 119/331 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs1253880438; called by muse, mutect2, varscan2
- ZC3H12B | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV59047911; called by muse, mutect2, varscan2
- ZDBF2 | c.5921G>T p.R1974L | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65623210, COSV65629189; called by muse, mutect2, varscan2
- ZEB2 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV57969375; called by muse, mutect2, varscan2
- ZFHX4 | c.5276C>T p.S1759F | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV50880508; called by muse, mutect2, varscan2
- ZFHX4 | c.5465C>T p.P1822L | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1459188683; called by muse, mutect2, varscan2
- ZNF142 | c.3755dup p.R1253Tfs*15 (on ENST00000411696 / NM_001379660.1; = p.R1053Tfs*15 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 50/156 reads (32%) | catalogued as rs751589999; called by mutect2, varscan2
- ZNF143 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs770679871; called by muse, mutect2, varscan2
- ZNF358 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.35); catalogued as rs1313300427; called by muse, mutect2, varscan2
- ZNF417 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.025); catalogued as rs1277288095; called by muse, mutect2
- ZNF48 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100198036; called by mutect2, varscan2
- ZNF526 | c.1243G>T p.A415S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV55900503; called by muse, mutect2
- ZNF578 | c.1433C>A p.T478N | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs746409386; called by muse, mutect2, varscan2
- ZNF711 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs777967143, COSV52152649; called by muse, mutect2, varscan2
- ZNF728 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as COSV74099543; called by muse, mutect2, varscan2
- ZNF831 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64041565; called by muse, mutect2, varscan2
- ZSWIM2 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 18/404 reads (4%) | catalogued as COSV54573647; called by muse, mutect2
- AAMP | c.844T>C p.C282R | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- ABCB1 | c.1357G>T p.V453F | Missense Mutation (SNP) | VAF 219/743 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ABCB5 | c.3317G>T p.S1106I (on ENST00000404938 / NM_001163941.2; = p.S661I on NM_178559.6) | Missense Mutation (SNP) | VAF 161/470 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ABCB8 | c.616G>T p.G206* (on ENST00000297504 / NM_001282291.2; = p.G189* on NM_007188.5) | Nonsense Mutation (SNP) | VAF 45/188 reads (24%) | called by muse, mutect2, varscan2
- ABCC9 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ABHD13 | c.532A>T p.T178S | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AC011005.1 | c.873C>A p.H291Q | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC104389.6 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 110/433 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ACACA | c.5291C>A p.A1764E | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACOT12 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADA | c.362+5G>T | Splice Region (SNP) | VAF 91/400 reads (23%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.2644G>T p.G882C | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS5 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ADD2 | c.555+1G>T p.X185_splice | Splice Site (SNP) | VAF 72/228 reads (32%) | called by muse, mutect2, varscan2
- ADGB | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRD1 | c.1681G>T p.G561* | Nonsense Mutation (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4615C>A p.H1539N (on ENST00000506720 / NM_001322402.2; = p.H1428N on NM_015236.6) | Missense Mutation (SNP) | VAF 159/498 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADHFE1 | c.888G>T p.R296S | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- AHNAK2 | c.1325C>A p.P442Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AKAP4 | c.2185G>T p.A729S | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALB | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 94/388 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALB | c.938G>T p.C313F | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH1L1 | c.2292T>A p.H764Q | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANGPTL1 | c.1089T>A p.D363E | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ANKK1 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANKS1B | c.740A>G p.E247G | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- AP002512.3 | c.429G>T p.L143F | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- APLNR | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.605); called by muse, mutect2
- APOL5 | c.655A>T p.N219Y | Missense Mutation (SNP) | VAF 39/599 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2
- APPL1 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 89/283 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- AQP10 | c.371-1G>T p.X124_splice | Splice Site (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- AR | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 95/198 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP39 | c.1785G>T p.M595I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ARHGEF26 | c.1867G>C p.G623R | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGEF28 | c.1024+1G>T p.X342_splice | Splice Site (SNP) | VAF 42/138 reads (30%) | called by muse, mutect2, varscan2
- ARID2 | c.2179G>T p.G727* | Nonsense Mutation (SNP) | VAF 64/238 reads (27%) | called by muse, mutect2, varscan2
- ARVCF | c.2784C>A p.L928= | Splice Region (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- ASTN2 | c.1627C>A p.P543T (on ENST00000313400 / NM_001365069.1; = p.P492T on NM_014010.5) | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ASXL2 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATF6 | c.1534G>T p.G512C | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); called by muse, varscan2
- ATG2A | c.5273-1G>A p.X1758_splice | Splice Site (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2503A>T p.M835L (on ENST00000545399 / NM_001256214.2; = p.M822L on NM_152296.5) | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ATP2B1 | c.2443-1G>T p.X815_splice | Splice Site (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- ATRNL1 | c.3751G>T p.V1251L | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- BAHCC1 | c.6925G>C p.A2309P | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- BCL2L12 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BEND5 | c.226+1G>T p.X76_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- BICRAL | c.784G>C p.G262R | Missense Mutation (SNP) | VAF 68/360 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPTF | c.1114C>G p.L372V | Missense Mutation (SNP) | VAF 83/351 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- BRS3 | c.1022T>A p.F341Y | Missense Mutation (SNP) | VAF 90/154 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRWD1 | c.2950A>T p.I984F | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- C10orf71 | c.2768G>T p.R923L | Missense Mutation (SNP) | VAF 166/498 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C1QTNF4 | c.627C>A p.N209K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2CD2 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- C3orf20 | c.2234C>A p.P745H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C4orf54 | c.4747A>G p.S1583G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- C8orf34-AS1 | n.529-1G>T | Splice Site (SNP) | VAF 49/186 reads (26%) | called by muse, mutect2, varscan2
- CA6 | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 81/280 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1E | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CALCRL | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CAMSAP2 | c.1345A>C p.S449R (on ENST00000236925 / NM_001297707.2; = p.S438R on NM_203459.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CASC3 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CASP12 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP2 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 156/702 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CASP5 | c.571C>A p.R191S | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CASP5 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CCDC116 | c.1559G>C p.S520T | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC168 | c.12977G>T p.S4326I | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- CCDC81 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 94/407 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCSER2 | c.1712G>T p.C571F | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2
- CD19 | c.797T>A p.L266Q | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CDH12 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CDH17 | c.2327C>A p.A776E | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2
- CDH23 | c.8083G>T p.D2695Y | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH4 | c.649A>T p.M217L | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CDHR4 | c.1861C>A p.R621S | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDIN1 | c.543A>T p.L181= (on ENST00000437989; = p.L83= on NM_032499.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 60/153 reads (39%) | called by muse, mutect2, varscan2
- CELF2 | c.224G>A p.R75Q (on ENST00000416382 / NM_001025077.3; = p.R82Q on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CENPE | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CEP170 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 70/593 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP250 | c.4499A>G p.E1500G | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CEP43 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CERS5 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- CFHR4 | c.94G>C p.G32R (on ENST00000367416 / NM_001201551.2; = p.G33R on NM_006684.5) | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CHST15 | c.1505G>T p.S502I | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CILP | c.530G>C p.C177S | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCN1 | c.2413T>C p.W805R | Missense Mutation (SNP) | VAF 102/514 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- CLCN1 | c.2436G>T p.Q812H | Missense Mutation (SNP) | VAF 200/560 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, varscan2
- CNGA3 | c.1668G>T p.K556N | Missense Mutation (SNP) | VAF 187/622 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CNNM1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CNTLN | c.1556A>T p.K519M | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL12A1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL20A1 | c.2540T>A p.V847E | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A1 | c.4246A>T p.T1416S | Missense Mutation (SNP) | VAF 97/526 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL5A1 | c.1936-1G>T p.X646_splice | Splice Site (SNP) | VAF 98/386 reads (25%) | called by muse, varscan2
- CPA3 | c.177C>A p.H59Q | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPLANE1 | c.267G>T p.W89C (on ENST00000425232; = p.W161C on NM_023073.3) | Missense Mutation (SNP) | VAF 61/454 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPLANE1 | c.266G>T p.W89L (on ENST00000425232; = p.W161L on NM_023073.3) | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPSF1 | c.3877G>A p.G1293S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPVL | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CR1 | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 85/390 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CRACD | c.2505G>T p.M835I | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CRCT1 | c.77C>A p.A26D | Missense Mutation (SNP) | VAF 25/139 reads (18%) | PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CRYBG2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CSMD1 | c.3560C>T p.T1187I (on ENST00000520002; = p.T1186I on NM_033225.6) | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTNND2 | c.1373-1G>T p.X458_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.813G>T p.R271S | Missense Mutation (SNP) | VAF 85/306 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTTNBP2 | c.812G>T p.R271M | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CYGB | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CYP2W1 | c.1220C>A p.P407H | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAG1 | c.217G>T p.V73F | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.869); called by muse, mutect2
- DCAF8L2 | c.893G>C p.R298P | Missense Mutation (SNP) | VAF 105/200 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCP1A | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 70/215 reads (33%) | called by muse, mutect2, varscan2
- DDX53 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX60 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DENND2A | c.1087A>T p.T363S | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DENND4B | c.1076A>T p.H359L | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- DENND5A | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 148/511 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX58 | c.468G>C p.R156S | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DISC1 | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- DKK4 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- DLEC1 | c.1670del p.L557Cfs*7 | Frame Shift Del (DEL) | VAF 60/266 reads (23%) | called by mutect2, pindel, varscan2
- DLK1 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DLL3 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 127/477 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DLST | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 49/370 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH11 | c.12484G>C p.E4162Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.093); called by muse, mutect2
- DPM2 | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- DSCAM | c.2691A>T p.K897N | Missense Mutation (SNP) | VAF 156/651 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- EBI3 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ECT2L | c.551_552del p.K184Mfs*14 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | called by pindel, varscan2
- EFHD1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 35/117 reads (30%) | called by muse, mutect2, varscan2
- EFNA1 | c.532A>T p.S178C | Missense Mutation (SNP) | VAF 111/565 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EIF3L | c.1154G>A p.S385N | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.317); called by muse, mutect2
- ELFN1 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- EML5 | c.4333G>T p.A1445S (on ENST00000380664; = p.A1453S on NM_183387.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); called by muse, mutect2
- EN2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2
- EPHA1 | c.611G>C p.C204S | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPRS1 | c.1810A>G p.T604A | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- ERVV-2 | c.1291C>A p.H431N | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ESR1 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 74/319 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ESYT2 | c.1503G>C p.L501F (on ENST00000613624; = p.L425F on NM_020728.3) | Missense Mutation (SNP) | VAF 81/473 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM171B | c.956C>A p.T319K | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, varscan2
- FAM189B | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- FAM241B | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 124/596 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM83B | c.2575G>T p.A859S | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.3968G>T p.S1323I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- FBN2 | c.8365-2A>T p.X2789_splice | Splice Site (SNP) | VAF 94/257 reads (37%) | called by muse, mutect2, varscan2
- FBXL7 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- FCGBP | c.5478G>T p.Q1826H | Missense Mutation (SNP) | VAF 82/1080 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.17); called by muse, mutect2
- FCGBP | c.3451C>A p.L1151M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FCGR2C | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FCGR2C | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FCRL4 | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 109/613 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- FER1L6 | c.1131G>T p.M377I | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGF20 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 134/580 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, varscan2
- FNDC7 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 136/539 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOLH1 | c.1604C>A p.A535E | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- FREM3 | c.2611G>T p.G871C | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); called by mutect2, varscan2
- FSIP2 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, varscan2
- FYB1 | c.710C>G p.P237R | Missense Mutation (SNP) | VAF 115/660 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- FYCO1 | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); called by muse, mutect2
- GALNT13 | c.1650G>T p.R550S | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GALNT16 | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GAPDHS | c.346T>A p.Y116N | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAS2L2 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATB | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GJA1 | c.1121G>T p.R374I | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- GLB1L | c.1371G>A p.M457I | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GOLGA6L22 | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT deleterious (0); called by muse, varscan2
- GOLGA8J | c.1068G>T p.R356S | Missense Mutation (SNP) | VAF 137/459 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- GPR25 | c.783C>A p.S261R | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- GPR6 | c.757T>C p.W253R | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRAMD1A | c.1476-1G>A p.X492_splice | Splice Site (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- GRIK4 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GUCY1A2 | c.1885del p.V629Cfs*38 | Frame Shift Del (DEL) | VAF 55/281 reads (20%) | called by mutect2, pindel, varscan2
- GUCY2C | c.218-1G>T p.X73_splice | Splice Site (SNP) | VAF 58/165 reads (35%) | called by muse, mutect2, varscan2
- HAAO | c.185T>C p.M62T | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HABP2 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 46/482 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HACE1 | c.2479G>T p.E827* | Nonsense Mutation (SNP) | VAF 42/241 reads (17%) | called by muse, varscan2
- HAPLN1 | c.472+3A>T | Splice Region (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- HAUS4 | c.840-1G>T p.X280_splice | Splice Site (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- HBD | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 72/667 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HCN1 | c.940dup p.C314Lfs*22 | Frame Shift Ins (INS) | VAF 72/466 reads (15%) | called by pindel, varscan2
- HHIP | c.1248C>G p.N416K | Missense Mutation (SNP) | VAF 97/434 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HIF3A | c.1862G>T p.G621V (on ENST00000377670 / NM_152795.4; = p.G552V on NM_022462.4) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.145); called by muse, mutect2
- HIP1R | c.1242_1246del p.E415Gfs*18 | Frame Shift Del (DEL) | VAF 44/166 reads (27%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.4603G>T p.E1535* | Nonsense Mutation (SNP) | VAF 39/236 reads (17%) | called by muse, mutect2, varscan2
- HLTF | c.1832G>T p.R611I | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HMCN1 | c.13881dup p.N4628Efs*11 | Frame Shift Ins (INS) | VAF 134/743 reads (18%) | called by mutect2, pindel, varscan2
- HNRNPA0 | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, varscan2
- HS3ST1 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); called by mutect2, varscan2
- HS6ST3 | c.1321C>A p.Q441K | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HSPA13 | c.576dup p.A193Cfs*11 | Frame Shift Ins (INS) | VAF 40/197 reads (20%) | called by mutect2, pindel
- HSPH1 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HYAL4 | c.644G>T p.W215L | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2
- IGKV1D-13 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.207); called by mutect2, varscan2
- IGSF10 | c.3565C>A p.P1189T | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IL10RA | c.727G>T p.V243F | Missense Mutation (SNP) | VAF 68/824 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- IL12RB1 | c.1286T>A p.L429* | Nonsense Mutation (SNP) | VAF 44/150 reads (29%) | called by muse, mutect2, varscan2
- INHBA | c.1214A>T p.D405V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGA8 | c.2725C>A p.H909N | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGB6 | c.834G>T p.M278I | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- KCNB2 | c.2106C>A p.S702R | Missense Mutation (SNP) | VAF 99/371 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KCNH1 | c.999G>T p.Q333H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- KCNH3 | c.1543C>G p.H515D | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KCNT1 | c.2295C>A p.G765= (on ENST00000488444; = p.G784= on NM_020822.3) | Splice Region (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- KDR | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 150/350 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, varscan2
- KIAA0232 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KIF13B | c.4957G>T p.A1653S | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF15 | c.2315A>G p.Q772R | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF16B | c.2305C>T p.L769F | Missense Mutation (SNP) | VAF 115/448 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- KIF2B | c.1733G>T p.R578M | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- KIR2DL4 | c.632C>G p.P211R (on ENST00000396284; = p.P172R on NM_001080770.2) | Missense Mutation (SNP) | VAF 86/383 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.018); called by muse, varscan2
- KIRREL1 | c.1145A>T p.E382V | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- KLHL33 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLRG1 | c.558+3C>T | Splice Region (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2, varscan2
- KMO | c.1306A>T p.S436C | Missense Mutation (SNP) | VAF 86/486 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- KMT2B | c.2825G>C p.G942A | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2C | c.2904A>T p.Q968H | Missense Mutation (SNP) | VAF 21/358 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- KRT1 | c.1277T>A p.I426N | Missense Mutation (SNP) | VAF 157/560 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP10-3 | c.77G>C p.C26S | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- KRTAP27-1 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- LAPTM5 | c.785T>A p.V262E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LARGE1 | c.744del p.T249Lfs*51 | Frame Shift Del (DEL) | VAF 69/530 reads (13%) | called by mutect2, pindel, varscan2
- LARP4B | c.2087C>A p.P696H | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- LCN6 | c.179T>G p.V60G | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.516); called by muse, varscan2
- LCT | c.2579C>A p.T860K | Missense Mutation (SNP) | VAF 101/408 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- LCT | c.2577T>A p.N859K | Missense Mutation (SNP) | VAF 102/418 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- LGR5 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 99/429 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- LMO1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMO7 | c.1065G>T p.W355C (on ENST00000357063; = p.W85C on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2
- LOXL3 | c.458C>A p.S153* | Nonsense Mutation (SNP) | VAF 47/138 reads (34%) | called by muse, varscan2
- LPA | c.5274del p.T1759Qfs*27 | Frame Shift Del (DEL) | VAF 60/487 reads (12%) | called by mutect2, pindel, varscan2
- LPA | c.4291G>C p.G1431R | Missense Mutation (SNP) | VAF 106/457 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- LRRC4B | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LSAMP | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 132/507 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MACF1 | c.16749G>T p.E5583D (on ENST00000372915; = p.E3625D on NM_012090.5) | Missense Mutation (SNP) | VAF 98/471 reads (21%) | called by muse, mutect2, varscan2
- MAGI1 | c.4085G>T p.R1362M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MARCHF6 | c.408-1G>C p.X136_splice | Splice Site (SNP) | VAF 85/555 reads (15%) | called by muse, mutect2, varscan2
- MARCO | c.1151C>A p.A384E | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- MCM9 | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- MCPH1 | c.1235A>T p.Y412F | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDN1 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MED12L | c.1318G>T p.V440F | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.035); called by muse, varscan2
- MED16 | c.2002C>G p.L668V | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MEIS1 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 134/539 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- METTL18 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2
- MFSD11 | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MGAM2 | c.2269G>T p.G757C | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); called by muse, varscan2
- MGAM2 | c.5728G>C p.G1910R | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated, low confidence (0.46); called by muse, mutect2, varscan2
- MKI67 | c.3045A>G p.I1015M | Missense Mutation (SNP) | VAF 332/846 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- MMS22L | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MON2 | c.4939A>T p.K1647* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- MPEG1 | c.149del p.G50Afs*16 | Frame Shift Del (DEL) | VAF 97/478 reads (20%) | called by mutect2, pindel, varscan2
- MPHOSPH10 | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MRAP2 | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MRC2 | c.2623A>T p.N875Y | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MRTFB | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 111/324 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MTUS2 | c.3303G>C p.E1101D (on ENST00000612955 / NM_001366650.1; = p.E80D on NM_015233.6) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- MUC16 | c.41811C>A p.Y13937* | Nonsense Mutation (SNP) | VAF 68/254 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.41079G>T p.R13693S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.884); called by muse, mutect2
- MUC16 | c.39883+1G>T p.X13295_splice | Splice Site (SNP) | VAF 33/159 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.26522G>T p.W8841L | Missense Mutation (SNP) | VAF 96/383 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MUC16 | c.9577G>T p.A3193S | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MUC17 | c.10109C>A p.P3370H | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, varscan2
- MUC2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- MYH15 | c.3885G>T p.E1295D | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MYO5A | c.2627G>T p.W876L | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- NALCN | c.4574G>C p.G1525A | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, varscan2
- NALCN | c.4539del p.K1513Nfs*22 | Frame Shift Del (DEL) | VAF 59/278 reads (21%) | called by pindel, varscan2
- NALCN | c.3397G>T p.G1133* | Nonsense Mutation (SNP) | VAF 30/187 reads (16%) | called by muse, mutect2, varscan2
- NBAS | c.4670C>T p.A1557V | Missense Mutation (SNP) | VAF 73/322 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NCOA1 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NCSTN | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 95/530 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- NDUFAF5 | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEBL | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 186/469 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NECTIN2 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- NEDD1 | c.-259A>T | Splice Region (SNP) | VAF 42/343 reads (12%) | called by muse, mutect2, varscan2
- NEK5 | c.810+1del p.X270_splice | Splice Site (DEL) | VAF 50/208 reads (24%) | called by mutect2, pindel, varscan2
- NF1 | c.7867_7869del p.L2623del (on ENST00000358273 / NM_001042492.3; = p.L2602del on NM_000267.3) | In Frame Del (DEL) | VAF 66/330 reads (20%) | called by mutect2, pindel, varscan2
- NGDN | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NHLRC4 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP5 | c.3163G>T p.E1055* | Nonsense Mutation (SNP) | VAF 51/162 reads (31%) | called by muse, mutect2, varscan2
- NLRP8 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.102); called by muse, mutect2
- NLRP8 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 58/419 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NME7 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- NOS2 | c.1287G>T p.Q429H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPAP1 | c.3130G>T p.G1044W | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NPC1L1 | c.2302G>C p.A768P | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPC2 | c.364-1G>T p.X122_splice | Splice Site (SNP) | VAF 65/470 reads (14%) | called by muse, mutect2, varscan2
- NPR1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NPY2R | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 77/350 reads (22%) | called by muse, mutect2, varscan2
- NR4A3 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- NR5A2 | c.697A>C p.T233P (on ENST00000367362 / NM_205860.3; = p.T187P on NM_003822.5) | Missense Mutation (SNP) | VAF 101/421 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRCAM | c.1546C>A p.Q516K (on ENST00000379028 / NM_001371124.1; = p.Q510K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NRK | c.2167C>A p.R723S | Missense Mutation (SNP) | VAF 79/136 reads (58%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN2 | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRXN3 | c.1207G>T p.G403C (on ENST00000335750 / NM_001330195.2; = p.G30C on NM_004796.6) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NTNG1 | c.290del p.P97Lfs*9 | Frame Shift Del (DEL) | VAF 44/133 reads (33%) | called by mutect2, pindel, varscan2
- NTSR2 | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- NUDT6 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 53/264 reads (20%) | called by muse, mutect2, varscan2
- OAS2 | c.971T>A p.L324Q | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- OLFM4 | c.1328C>A p.T443N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR10G3 | c.65G>T p.R22M | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- OR10J3 | c.699A>T p.E233D | Missense Mutation (SNP) | VAF 133/808 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- OR12D3 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- OR1S1 | c.190T>A p.L64M | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- OR2T1 | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 89/470 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR2T27 | c.922T>C p.C308R | Missense Mutation (SNP) | VAF 163/302 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR4A15 | c.150C>A p.S50R | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR4K13 | c.729C>A p.H243Q | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4Q2 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR51F2 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.781); called by muse, varscan2
- OR5B17 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); called by muse, varscan2
- OR5I1 | c.554_555delinsT p.P185Lfs*44 | Frame Shift Del (DEL) | VAF 25/150 reads (17%) | called by pindel, varscan2*
- OR6F1 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 145/578 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8H2 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OSTF1 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- OTOF | c.5450G>C p.W1817S (on ENST00000272371 / NM_194248.3; = p.W1050S on NM_004802.4) | Missense Mutation (SNP) | VAF 87/330 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- OTUD7A | c.1078A>G p.R360G (on ENST00000307050 / NM_001382637.1; = p.R353G on NM_130901.3) | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- PAK5 | c.1452del p.K484Nfs*13 | Frame Shift Del (DEL) | VAF 44/179 reads (25%) | called by mutect2, pindel, varscan2
- PAPLN | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PAQR9 | c.307del p.R103Vfs*5 | Frame Shift Del (DEL) | VAF 47/220 reads (21%) | called by mutect2, pindel, varscan2
- PAX2 | c.688G>T p.V230L (on ENST00000428433 / NM_003987.5; = p.V207L on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- PAX5 | c.909A>T p.T303= | Splice Region (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2
- PAX6 | c.1224del p.G409Efs*? (on ENST00000241001 / NM_001127612.3; = p.G409Efs*116 on NM_000280.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 70/362 reads (19%) | called by mutect2, pindel, varscan2
- PAX9 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 28/389 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCDHA12 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 118/333 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.673); called by muse, varscan2
- PCDHA2 | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PCDHGB6 | c.1570C>A p.Q524K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCGF2 | c.338_344del p.D113Afs*11 | Frame Shift Del (DEL) | VAF 44/211 reads (21%) | called by mutect2, pindel, varscan2
- PCLO | c.10325A>T p.D3442V | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PDE4DIP | c.5723G>T p.R1908M | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PDXDC1 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); called by muse, mutect2
- PEX2 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 90/367 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- PHF13 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- PI3 | c.79+2T>C p.X27_splice | Splice Site (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- PIF1 | c.113T>A p.L38Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- PIKFYVE | c.3958A>T p.K1320* | Nonsense Mutation (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- PITX2 | c.808C>G p.P270A (on ENST00000354925 / NM_001204397.1; = p.P277A on NM_000325.6) | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- PKD2 | c.2368G>T p.D790Y | Missense Mutation (SNP) | VAF 130/595 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PKHD1L1 | c.5679T>A p.D1893E | Missense Mutation (SNP) | VAF 116/482 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHG3 | c.591G>C p.E197D (on ENST00000394691; = p.E253D on NM_001308147.2) | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- PLXNA4 | c.3236G>T p.G1079V | Missense Mutation (SNP) | VAF 106/412 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PLXNA4 | c.2641del p.E881Rfs*24 | Frame Shift Del (DEL) | VAF 36/349 reads (10%) | called by mutect2, pindel, varscan2
- PLXNC1 | c.2480G>T p.R827I | Missense Mutation (SNP) | VAF 132/503 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- PNLIP | c.51A>C p.K17N | Missense Mutation (SNP) | VAF 60/675 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2
- PPFIA4 | c.1779G>T p.E593D (on ENST00000447715; = p.E594D on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- PPP1R37 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PPP6R1 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRR22 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR23B | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR7 | c.635C>G p.S212W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PSD2 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PSMF1 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PTGFRN | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 88/420 reads (21%) | called by muse, mutect2, varscan2
- PTPN12 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PTPN5 | c.767C>G p.P256R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PTPN9 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PTPRH | c.1751G>T p.W584L | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PTPRZ1 | c.1831T>A p.S611T | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTPRZ1 | c.5497G>C p.G1833R | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTRH1 | c.-1321+4A>G | Splice Region (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- RANBP3 | c.99C>G p.N33K | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAP1A | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- RAPGEF1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RARB | c.1171+1G>T p.X391_splice (on ENST00000383772 / NM_001290216.2; = p.X384_splice on NM_000965.5 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 18/76 reads (24%) | called by muse, varscan2
- RARG | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASSF8 | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- RASSF8 | c.582G>T p.W194C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- RBM12 | c.1831G>T p.G611W | Missense Mutation (SNP) | VAF 96/445 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REM1 | c.341-2A>T p.X114_splice | Splice Site (SNP) | VAF 34/154 reads (22%) | called by muse, mutect2, varscan2
- RER1 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 77/477 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- RFX8 | c.1284C>A p.D428E (on ENST00000646446; = p.D357E on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/508 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- RGS22 | c.3413G>T p.R1138M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- RIPK4 | c.2345A>T p.Q782L (on ENST00000352483; = p.Q734L on NM_020639.3) | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- RIPOR1 | c.2029C>A p.L677I (on ENST00000379312 / NM_001193522.2; = p.L673I on NM_024519.4) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RIPOR3 | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- RNASEH2B | c.407A>T p.K136M | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- RNF144A | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 137/526 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNF32 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 32/317 reads (10%) | called by muse, mutect2, varscan2
- RNF6 | c.1009A>T p.T337S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF6 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 24/421 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- RPAP1 | c.1913G>T p.R638L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPIA | c.62G>T p.R21M | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RPL6 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, varscan2
- RPS24 | c.586T>A p.W196R | Missense Mutation (SNP) | VAF 111/708 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- RRAGB | c.557dup p.L186Ffs*18 (on ENST00000262850 / NM_016656.4; = p.L158Ffs*18 on NM_006064.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 46/111 reads (41%) | called by mutect2, pindel, varscan2
- RRM2 | c.960G>T p.M320I | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.476); called by muse, mutect2
- RSKR | c.1226C>G p.P409R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RSRC1 | c.582T>C p.A194= | Splice Region (SNP) | VAF 49/159 reads (31%) | called by muse, mutect2, varscan2
- RTL1 | c.3482A>T p.Q1161L | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RTTN | c.68A>T p.K23M | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- RYR2 | c.1991G>C p.S664T | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.201); called by muse, varscan2
- RYR2 | c.5748C>A p.C1916* | Nonsense Mutation (SNP) | VAF 46/183 reads (25%) | called by muse, mutect2, varscan2
- SARM1 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SCN11A | c.3564_3576del p.W1189Vfs*23 | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | called by mutect2, pindel
- SCP2D1 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- SCYL2 | c.969G>C p.K323N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SEMA6A | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 94/340 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- SEMA6C | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SEMA6D | c.2384C>A p.A795D (on ENST00000316364 / NM_153618.2; = p.A733D on NM_020858.2) | Missense Mutation (SNP) | VAF 98/260 reads (38%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- SERPINE2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 54/794 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2
- SERTAD2 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 24/243 reads (10%) | called by mutect2, varscan2
- SETX | c.2008G>C p.E670Q | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SFTPB | c.1129C>G p.H377D | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SHANK1 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SIGLEC6 | c.1247C>A p.P416H | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, varscan2
- SIGLEC8 | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SIPA1L2 | c.3295G>T p.A1099S | Missense Mutation (SNP) | VAF 78/499 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLAMF8 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC11A1 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SLC13A3 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A1 | c.1457A>G p.Q486R | Missense Mutation (SNP) | VAF 105/336 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC25A44 | c.132dup p.L45Vfs*51 | Frame Shift Ins (INS) | VAF 112/714 reads (16%) | called by mutect2, pindel, varscan2
- SLC26A3 | c.1600G>T p.G534* | Nonsense Mutation (SNP) | VAF 136/606 reads (22%) | called by muse, mutect2, varscan2
- SLC34A2 | c.949C>G p.P317A | Missense Mutation (SNP) | VAF 71/376 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- SLC35E4 | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- SLC35F3 | c.1048A>G p.S350G (on ENST00000366617 / NM_001300845.1; = p.S419G on NM_173508.4) | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.098); called by muse, varscan2
- SLC39A12 | c.1348G>T p.G450* | Nonsense Mutation (SNP) | VAF 141/285 reads (49%) | called by muse, mutect2, varscan2
- SLC6A1 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 102/360 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A18 | c.1785G>T p.R595S | Missense Mutation (SNP) | VAF 98/494 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SLC6A3 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 132/680 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC8A3 | c.595C>G p.H199D | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLFN11 | c.2278T>A p.C760S | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK2 | c.2182G>T p.E728* | Nonsense Mutation (SNP) | VAF 56/114 reads (49%) | called by muse, mutect2, varscan2
- SLITRK4 | c.1266del p.H422Qfs*39 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- SNRNP200 | c.3065C>G p.S1022C | Missense Mutation (SNP) | VAF 95/706 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SOHLH1 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 73/245 reads (30%) | called by muse, mutect2, varscan2
- SORCS3 | c.1047T>A p.D349E | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SPANXD | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 119/232 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SPEG | c.7262C>A p.P2421H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- SPINK5 | c.2230A>G p.K744E | Missense Mutation (SNP) | VAF 112/313 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SPTA1 | c.2351C>A p.T784N | Missense Mutation (SNP) | VAF 115/706 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SPTA1 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 140/770 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- SPTBN1 | c.2734G>C p.A912P | Missense Mutation (SNP) | VAF 103/434 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SRRM2 | c.5960C>G p.S1987C | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- STARD7 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SUGP1 | c.1677G>T p.K559N | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SUN3 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SUOX | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SVEP1 | c.25T>A p.C9S | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SYNE1 | c.21269A>G p.Q7090R (on ENST00000367255 / NM_182961.4; = p.Q7019R on NM_033071.3) | Missense Mutation (SNP) | VAF 54/401 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SYNE1 | c.14697G>T p.W4899C (on ENST00000367255 / NM_182961.4; = p.W4828C on NM_033071.3) | Missense Mutation (SNP) | VAF 102/413 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SYNE3 | c.2517G>T p.R839S | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SYP | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 85/142 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYPL2 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TAS2R31 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- TBC1D3I | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TBCD | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 27/125 reads (22%) | called by muse, mutect2, varscan2
- TBX19 | c.392_403del p.F131_H134del | In Frame Del (DEL) | VAF 83/437 reads (19%) | called by mutect2, pindel, varscan2
- TCEA1 | c.797G>T p.C266F | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCHH | c.4054C>A p.P1352T | Missense Mutation (SNP) | VAF 78/412 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCTEX1D1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX10 | c.1665_1670del p.P556_L557del | In Frame Del (DEL) | VAF 37/136 reads (27%) | called by pindel, varscan2
- TEX13C | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- THEG | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- TLK2 | c.1692G>C p.E564D (on ENST00000326270 / NM_001284333.2; = p.E542D on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TMED4 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 164/531 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TMEM123 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- TMEM72 | c.299C>A p.S100* | Nonsense Mutation (SNP) | VAF 64/265 reads (24%) | called by muse, mutect2, varscan2
- TNN | c.1375G>T p.A459S | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TNS3 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TONSL | c.3679del p.A1227Qfs*24 | Frame Shift Del (DEL) | VAF 34/149 reads (23%) | called by mutect2, pindel, varscan2
- TOP1MT | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TPX2 | c.1519del p.E507Nfs*3 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- TRHDE | c.2147A>T p.N716I | Missense Mutation (SNP) | VAF 102/489 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TRIM64C | c.1277G>C p.G426A | Missense Mutation (SNP) | VAF 173/540 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRPM2 | c.2360G>T p.R787L | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- TRPM6 | c.2538+1del p.X846_splice | Splice Site (DEL) | VAF 94/450 reads (21%) | called by mutect2, pindel, varscan2
- TSPYL5 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TTC21A | c.3433G>T p.A1145S | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TTC29 | c.301A>T p.R101W | Missense Mutation (SNP) | VAF 191/717 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- TTC8 | c.201G>T p.M67I (on ENST00000338104 / NM_001288781.1; = p.M77I on NM_144596.4) | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
382 further variants in this file (48 protein-altering or splice-affecting, 214 silent, 120 other) are not listed here.
